Somatic mutation profile of tumor specimen TCGA-KO-8405-01A (aliquot TCGA-KO-8405-01A-11D-2310-10) from TCGA case TCGA-KO-8405, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 29.2 years (10,671 days).
Specimen TCGA-KO-8405-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb6107b7-27ef-49a0-a1be-408173740190.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KO-8405-11A (Solid Tissue Normal), aliquot TCGA-KO-8405-11A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/36eba069-06db-4cc1-852c-0591de608abe

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCR2 | c.828C>A p.N276K | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.506); catalogued as COSV99432226; called by muse, mutect2, varscan2
- SARDH | c.2163+1G>T p.X721_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100898363; called by muse, mutect2
- SPATA31E1 | c.841C>G p.L281V | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.223); catalogued as COSV100349699; called by muse, mutect2, varscan2
- VPS37D | c.404A>G p.E135G | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100265262; called by muse, mutect2
- ZNF793 | c.593C>G p.T198S | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV71325093; called by muse, mutect2, varscan2
- BCLAF3 | c.658A>T p.R220* | Nonsense Mutation (SNP) | VAF 62/194 reads (32%) | called by muse, mutect2, varscan2
- ZNF106 | c.4916C>T p.T1639I | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- FAM131C | c.456C>T p.V152= | Silent (SNP) | VAF 19/108 reads (18%) | catalogued as rs745555665, COSV100989652; called by muse, varscan2
- PLEKHM1 | c.2670G>C p.L890= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV101378689; called by muse, mutect2, varscan2
- AL512625.1 | n.291C>T | RNA (SNP) | VAF 4/38 reads (11%) | catalogued as rs566074479; called by muse, mutect2
